Somatic mutation profile of tumor specimen TCGA-AA-3812-01A (aliquot TCGA-AA-3812-01A-01W-0900-09) from TCGA case TCGA-AA-3812, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 82.1 years (29,980 days).
Specimen TCGA-AA-3812-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95bd1919-0d6a-4f51-ae73-c21bde000a3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3812-10A (Blood Derived Normal), aliquot TCGA-AA-3812-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0ea04bd-60c7-4694-892d-675ca0534885

The open-access MAF lists 124 somatic variants for this specimen: 92 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 31, Frame Shift Del 4, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 2, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM18 | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV55844801, COSV99695436; called by muse, mutect2, varscan2
- ADAMTS5 | c.365C>G p.A122G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as COSV53176531, COSV53179007; called by muse, mutect2, varscan2
- APC | c.1670T>C p.V557A | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV57330269, COSV57367148; called by muse, mutect2, varscan2
- APC | c.4261del p.S1421Vfs*52 | Frame Shift Del (DEL) | VAF 102/235 reads (43%) | catalogued as COSV57329162; called by mutect2, pindel, varscan2
- ARAP1 | c.2482T>A p.Y828N (on ENST00000393609 / NM_001040118.2; = p.Y583N on NM_015242.4) | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV61989893; called by muse, mutect2, varscan2
- ATP11A | c.1634T>A p.F545Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52107334; called by muse, mutect2, varscan2
- BARD1 | c.2039G>A p.W680* | Nonsense Mutation (SNP) | VAF 21/123 reads (17%) | catalogued as COSV53609744; called by muse, mutect2, varscan2
- BCKDHB | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779150907, COSV57510465; called by muse, mutect2, varscan2
- BRD4 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as rs201864530, COSV54583253; called by muse, mutect2, varscan2
- BSN | c.10861G>A p.D3621N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs778399298, COSV56514020, COSV56526071; called by muse, mutect2, varscan2
- CALCA | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.029); catalogued as rs782681062, COSV59027546; called by muse, mutect2, varscan2
- CD209 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV52650651; called by muse, mutect2, varscan2
- CEP290 | c.976_979del p.E326Ifs*8 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs1231036283; called by mutect2, pindel, varscan2
- CLCA4 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99760552; called by muse, mutect2
- CLN8 | c.660C>G p.D220E | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV58669868, COSV58670579; called by muse, mutect2, varscan2
- CREB5 | c.313G>A p.V105I (on ENST00000357727 / NM_182898.4; = p.V98I on NM_004904.3) | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV63218184; called by muse, mutect2, varscan2
- CYP2C19 | c.874G>C p.A292P | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.32); catalogued as COSV100990553, COSV64907071; called by muse, mutect2, varscan2
- DISP1 | c.4214C>T p.T1405M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.057); catalogued as rs776835311, COSV52655877; called by muse, mutect2, varscan2
- EFCAB7 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs372824134; called by muse, mutect2, varscan2
- EIF2A | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs1318725183, COSV99855977; called by muse, mutect2
- EIF3A | c.3350G>A p.R1117Q | Missense Mutation (SNP) | VAF 87/389 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs768823906, COSV64960672; called by muse, mutect2, varscan2
- ELAVL1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60965993; called by muse, mutect2, varscan2
- EVA1A | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV52057174; called by muse, mutect2, varscan2
- EVX2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV57962699; called by muse, mutect2, varscan2
- FAM234B | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs373610349; called by muse, mutect2, varscan2
- FAR2 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs139633375; called by muse, mutect2, varscan2
- GNPTG | c.780dup p.G261Rfs*38 | Frame Shift Ins (INS) | VAF 21/102 reads (21%) | catalogued as rs754893828; called by mutect2, pindel, varscan2
- GRIPAP1 | c.1272+2T>C p.X424_splice | Splice Site (SNP) | VAF 107/784 reads (14%) | catalogued as rs782676872, COSV100904308; called by muse, mutect2, varscan2
- GRM1 | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV51113753; called by muse, mutect2, varscan2
- H2AB1 | c.139C>A p.R47S | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV57704539; called by muse, mutect2, varscan2
- H2BC1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.872); catalogued as rs143128181, COSV51236825; called by muse, mutect2, varscan2
- HDAC4 | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61861076; called by muse, mutect2
- IL2RG | c.1082dup p.C362Mfs*7 | Frame Shift Ins (INS) | VAF 15/131 reads (11%) | catalogued as rs745545309; called by mutect2, varscan2
- ITIH6 | c.2481G>T p.R827S | Missense Mutation (SNP) | VAF 148/448 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54487172; called by muse, varscan2
- KCNA4 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs749396985, COSV100068726, COSV60251043; called by muse, mutect2, varscan2
- KCNS3 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 93/278 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs537401566, COSV58405721; called by muse, mutect2, varscan2
- KDM2A | c.2379G>T p.K793N | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.118); catalogued as COSV58188812; called by muse, mutect2, varscan2
- KIAA1217 | c.5321G>A p.R1774H | Missense Mutation (SNP) | VAF 141/318 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575450846, COSV56813401; called by muse, varscan2
- LAMC2 | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs144652590; called by muse, mutect2, varscan2
- MACO1 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); catalogued as COSV65475389; called by muse, mutect2, varscan2
- MAGED1 | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV58514710; called by muse, mutect2, varscan2
- MECP2 | c.911A>G p.K304R | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs267608550, CM023417, COSV57652249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEI1 | c.1826T>G p.L609R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV55901402; called by muse, mutect2, varscan2
- MGA | c.5452C>T p.R1818* (on ENST00000219905 / NM_001164273.1; = p.R1609* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 28/105 reads (27%) | catalogued as COSV54950284; called by muse, mutect2, varscan2
- MID1 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1452714186, COSV58192359; called by muse, mutect2, varscan2
- MOV10 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs201257888; called by muse, mutect2, varscan2
- MX1 | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.761); catalogued as rs758038928, COSV55818215; called by muse, mutect2, varscan2
- MYCBP2 | c.11245del p.V3749* (on ENST00000357337; = p.V3787* on NM_015057.5) | Frame Shift Del (DEL) | VAF 50/479 reads (10%) | catalogued as COSV62012174; called by mutect2, pindel, varscan2
- MYO5A | c.4744A>G p.T1582A | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV62557514; called by muse, mutect2, varscan2
- NOTCH3 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as rs530724830, COSV54628750; called by muse, mutect2
- NR0B1 | c.873G>T p.W291C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM051948, CM970069, COSV66763704; called by mutect2, varscan2
- NUAK1 | c.832+2T>C p.X278_splice | Splice Site (SNP) | VAF 20/141 reads (14%) | catalogued as COSV54606124, COSV99777071; called by muse, mutect2, varscan2
- NUP107 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747623291, COSV57493528; called by muse, mutect2, varscan2
- OLFM4 | c.946A>T p.I316L | Missense Mutation (SNP) | VAF 65/401 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV54576149; called by muse, mutect2, varscan2
- PCDHA4 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63539537, COSV63540299; called by muse, mutect2, varscan2
- PCYT1A | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as COSV53056488; called by muse, mutect2, varscan2
- PDE4B | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58468645; called by muse, mutect2, varscan2
- PLCG2 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV63867849; called by muse, mutect2, varscan2
- PLD2 | c.1754C>A p.S585Y | Missense Mutation (SNP) | VAF 149/275 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV54004150; called by muse, mutect2, varscan2
- POSTN | c.780G>T p.L260F | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.589); catalogued as COSV65712141; called by muse, mutect2, varscan2
- RBM10 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100237916; called by muse, mutect2, varscan2
- RC3H1 | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV51198279; called by muse, mutect2, varscan2
- RIMS1 | c.1943G>T p.G648V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53441355, COSV53485124; called by muse, mutect2, varscan2
- SCN1B | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs757554677, COSV52893647; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57602874; called by muse, mutect2, varscan2
- SETBP1 | c.3131G>A p.S1044N | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.805); catalogued as COSV99953580; called by muse, mutect2, varscan2
- SIGLEC1 | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.836); catalogued as rs373105785; called by muse, mutect2, varscan2
- SIGLEC8 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as rs751514321, COSV58472557; called by muse, mutect2, varscan2
- SLC13A3 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs957403793, COSV51712648; called by muse, mutect2, varscan2
- SLC22A10 | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 72/313 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as rs1231774071, COSV60420386; called by muse, mutect2
- SLCO1B3 | c.1739G>A p.R580K | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53933820; called by muse, mutect2, varscan2
- SPACA7 | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV99366674; called by muse, mutect2
- SPSB4 | c.820T>C p.*274Rext*114 | Nonstop Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV60145726; called by muse, mutect2, varscan2
- SPTBN1 | c.3190C>G p.L1064V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV61686306; called by muse, mutect2, varscan2
- SRRM4 | c.1680A>C p.R560S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1218615612, COSV57422239; called by muse, varscan2
- STARD5 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 23/287 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100250855; called by muse, mutect2
- SWT1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as rs1364296965, COSV62253356; called by muse, mutect2, varscan2
- SYCP2L | c.2291T>C p.L764P | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51650983; called by muse, mutect2, varscan2
- TBX15 | c.1489G>A p.G497R (on ENST00000369429 / NM_001330677.2; = p.G391R on NM_152380.3) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.365); catalogued as rs940885857, COSV52868381; called by muse, mutect2, varscan2
- TFAP2C | c.1198T>A p.F400I | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52370655; called by muse, mutect2, varscan2
- TLX2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52046580; called by muse, mutect2
- TMEM179B | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV53667434; called by muse, mutect2, varscan2
- TMPRSS3 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.41); catalogued as rs766015335, COSV52300756, COSV52306513; called by muse, mutect2, varscan2
- TNK1 | c.1535G>A p.R512H (on ENST00000576812 / NM_001251902.2; = p.R507H on NM_003985.5) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs369367062; called by muse, mutect2, varscan2
- USP53 | c.1786A>G p.I596V | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs766390231, COSV56792890; called by muse, mutect2, varscan2
- VPS13D | c.3182G>A p.R1061Q | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs754405704, COSV50625382; called by muse, mutect2, varscan2
- VPS8 | c.3881G>A p.C1294Y (on ENST00000625842 / NM_001349294.1; = p.C1292Y on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV54981641; called by muse, mutect2, varscan2
- ZNF827 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV65225422, COSV65230154; called by muse, mutect2, varscan2
- ZNF831 | c.3176C>A p.T1059K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV64038132; called by muse, mutect2, varscan2
- IGHG1 | c.697A>C p.T233P | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, varscan2
- MGA | c.3888del p.L1297Wfs*39 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- BSX | c.522C>T p.D174= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV58005177; called by mutect2, varscan2
- C14orf93 | c.1551A>G p.Q517= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs1203589756, COSV52984616; called by muse, mutect2, varscan2
- COL19A1 | c.1371G>T p.L457= | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as COSV59567593; called by muse, mutect2, varscan2
- CYTH4 | c.1017C>T p.T339= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs754702190, COSV50631505; called by muse, mutect2, varscan2
- DBT | c.915C>G p.L305= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV64495021; called by muse, mutect2, varscan2
- DNAJC9 | c.657C>A p.A219= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV54350283; called by muse, mutect2
- FAT3 | c.13566C>T p.G4522= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs1228643144, COSV53084812; called by muse, mutect2, varscan2
- HEATR6 | c.1014T>C p.G338= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as COSV51744101; called by muse, mutect2, varscan2
- IL18BP | c.120C>T p.A40= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as COSV52620078; called by muse, mutect2, varscan2
- IQGAP3 | c.1776C>A p.I592= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as COSV63249995; called by muse, mutect2, varscan2
- IRS4 | c.2358C>T p.A786= | Silent (SNP) | VAF 96/246 reads (39%) | catalogued as COSV64532920; called by muse, mutect2, varscan2
- LRP2 | c.8589G>A p.T2863= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as rs762415291, COSV55542262; called by muse, mutect2
- MCTP1 | c.2862T>C p.S954= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1303683134, COSV56506685; called by muse, mutect2, varscan2
- NDUFA8 | c.324C>T p.D108= | Silent (SNP) | VAF 70/313 reads (22%) | catalogued as rs180920547, COSV65653292; called by muse, mutect2, varscan2
- NID1 | c.2517C>T p.C839= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as rs775151010, COSV51616107; called by muse, mutect2, varscan2
- PCDHB7 | c.1674G>A p.S558= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV50756292; called by muse, mutect2, varscan2
- PCDHGC4 | c.168G>A p.T56= | Silent (SNP) | VAF 39/194 reads (20%) | catalogued as rs1187424114, COSV52745588; called by muse, mutect2, varscan2
- PDILT | c.288C>T p.I96= | Silent (SNP) | VAF 44/218 reads (20%) | catalogued as rs566608055, COSV56699461; called by muse, mutect2, varscan2
- RCC1L | c.741T>C p.D247= | Silent (SNP) | VAF 24/197 reads (12%) | called by muse, mutect2, varscan2
- RGL1 | c.1707C>A p.G569= (on ENST00000360851 / NM_001297672.2; = p.G604= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV58980330; called by muse, mutect2, varscan2
- RXFP3 | c.258G>A p.V86= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100347581; called by muse, mutect2
- SEPHS1 | c.948C>T p.T316= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100525877; called by muse, mutect2, varscan2
- SMAD5 | c.1218C>T p.L406= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as rs371268695; called by muse, mutect2, varscan2
- ST3GAL2 | c.246C>T p.S82= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs747457859, COSV61595834; called by muse, mutect2, varscan2
- THEMIS | c.1437G>A p.L479= | Silent (SNP) | VAF 19/238 reads (8%) | catalogued as rs761511766, COSV100965417; called by muse, mutect2
- TRAPPC10 | c.840C>T p.N280= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as rs777027534, COSV52375925; called by muse, mutect2, varscan2
- TRIM16 | c.1143A>G p.T381= | Silent (SNP) | VAF 61/132 reads (46%) | catalogued as rs1486354997, COSV60885920; called by muse, mutect2, varscan2
- TSC22D1 | c.2007C>T p.S669= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs781265296, COSV71775311; called by muse, mutect2, varscan2
- WNT7B | c.945C>T p.T315= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV59748674; called by muse, mutect2, varscan2
- ZNF345 | c.498C>A p.I166= | Silent (SNP) | VAF 83/260 reads (32%) | catalogued as COSV59322866; called by muse, mutect2, varscan2
- ZNF609 | c.2958C>T p.S986= | Silent (SNP) | VAF 103/452 reads (23%) | catalogued as rs766800988, COSV58580682; called by muse, mutect2, varscan2
- DCHS2 | n.5751G>T | RNA (SNP) | VAF 36/184 reads (20%) | catalogued as COSV61768959; called by muse, mutect2, varscan2
